Surgical pathology report (de-identified scan), TCGA case TCGA-ND-A4WF, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Cedars Sinai, specimen TCGA-ND-A4WF-01A (Primary Tumor).

[page 1 of 3]
Patient:

Hospital No

Date Of Birth:

Age/Sex: F

Location:

Path #:

Pathologist:

Assistant:

Date of Procedure:

Date Received:

**SURGICAL PATHOLOGY REPORT****DIAGNOSIS:****A. UTERUS, BILATERAL TUBES AND OVARIES, RADICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:**

- **Malignant mixed mesodermal tumor (MMMT)**
- The tumor extensively involves the entire endometrial cavity (uterine fundus, anterior and posterior uterine corpus and lower uterine segment) and measures 16.0 x 15.0 x 10.0 cm
- The tumor invades the full thickness of the muscular uterine wall and penetrates the serosa
- Extensive lymphovascular space invasion identified
- The tumor involves the inked amputation site (point of transection of lower uterine segment)
- The left parametrium is involved by tumor
- Portion of omentum attached at the fundus is involved by tumor
- Right ovary shows a focal parenchymal involvement (0.2 cm), a 0.1 cm tumor deposit in the Hilar region and a 1.5 cm nodule in the right mesosalpinx
- The right ovary in addition shows surface epithelial inclusion glands, surface reactive mesothelial hyperplasia, fibrin and crushed nuclear debris
- Right fallopian tube shows surface involvement and foci of epithelial dysplasia (check this)
- Left ovary shows surface fibrin and detached tumor cell clusters
- Left fallopian tube shows adhesions with foci of atypia and mild hydrosalpinx
- Stage : pT3a Nx Mx

Cervix
Malignant 895013
Site: Fundus Uteri, 054.3
And 31/8/13

B. CERVICAL VAGINAL TUMOR, EXCISION:

- Fragments of fibromuscular soft tissue diffusely infiltrated by malignant mixed mesodermal tumor (MMMT)
- Excision includes portion of squamous mucosa
- Due to the fragmented nature of excision, margins cannot be assessed

NOTE: The malignant epithelial component is a mixed high-grade serous and endometrioid adenocarcinoma. The sarcomatous component is a high-grade pleomorphic sarcoma with features suggestive of a rhabdoid differentiation and fibrosarcomatous-type differentiation

HISTORY: Ovarian Cancer

MICROSCOPIC:

See diagnosis.

Patient Case(s):

Local

[page 2 of 3]
PATIENT:

PATH #:

SPECIAL STUDIES:

GROSS:

A. UTERUS, BILATERAL TUBES AND OVARIES

Labeled with the patient's name, labeled "uterus, bilateral tubes and ovaries", and received fresh in the OR for intraoperative gross consultation and subsequently fixed in formalin is a uterus with attached bilateral tubes and ovaries weighing 2400 grams. The uterus measures 19.0 cm from fundus to amputation site, 16.0 cm from right to left, and 10.0 cm from anterior to posterior. The endometrial cavity measures 12.0 cm in length and up to 11.0 cm in width. The right ovary measures 2.2 x 1.3 x 1.0 cm. The right fallopian tube measures 9.0 cm in length and up to 1.0 cm in diameter. The left ovary measures 2.3 x 1.3 x 1.0 cm. The left fallopian tube measures 9.0 cm in length and averages 1.0 cm in diameter. A portion of omentum attached at the fundus measures 11.0 x 6.0 x 1.0 cm.

The endometrial cavity is filled with a large soft tan-red focally hemorrhagic and necrotic tumor mass which protrudes from the amputation site and measures 16.0 x 15.0 x 10.0 cm. The tumor extends to the anterior and posterior amputation sites which are inked black, extends through the uterine wall and focally invades the overlying serosa which is inked black. An area of serosal involvement on the posterior surface measures 3.0 x 2.0 cm. Several subserosal tumor nodules are found at the attachment site of the omentum to the fundus. The entire endometrium is involved by tumor. Sectioning of the tumor reveals a solid soft tan-red necrotic focally hemorrhagic and focally cystic cut surface.

The remaining serosa shows focal hemorrhage and scattered fibrous adhesions. The right ovary shows a few serosal adhesions. The right fallopian tube is fimbriated and the mesosalpinx contains a soft ovoid tan-red nodule which measures 1.5 x 1.3 x 1.3 cm. The left ovary shows some hemorrhagic adhesions. The distal 3.3 cm of the left fallopian tube is cystic and dilated and measures up to 1.8 cm in diameter. Sectioning portal fibrosis the distal end reveals a unilocular cavity filled with clear watery fluid. The lining shows focal soft pink-tan nodules which measure up to 1.0 cm. No fimbria are identified. A few additional smooth-walled paratubal cysts measure up to 1.3 cm. The myometrium measures up to 3.5 cm in thickness. No definite cervical tissue is identified.

Ink key: Anterior and posterior amputation sites - black, serosal involvement by tumor - black.

Representative sections are submitted.

Cassette key:

- A1. Inked anterior amputation site including tumor
- A2. Inked posterior amputation site including tumor
- A3. Right parametrium - 2
- A4. Left parametrium - 3
- A5, A6. One full thickness section each of posterior corpus with inked area of serosal tumor involvement - 1 each
- A7. One full thickness section of posterior corpus with tumor extending to the serosa
- A8, A9. One bisected full thickness section of posterior corpus with tumor extending to the serosa
- A10. One full thickness section of anterior corpus with tumor extending to the serosa
- A11, A12. One bisected full thickness section of anterior corpus with tumor extending to the serosa
- A13, A14. Tumor - 2 each
- A15. Omentum in relation to subserosal fundal tumor nodules - 2
- A16. Right ovary - 2
- A17. Right fallopian tube - 4
- A18. Nodule found within right mesosalpinx - 2
- A19. Left ovary - 2
- A20. Left fallopian tube and paratubal cyst - 4
- A21. Distal cystic left fallopian tube including soft pink-tan nodules - 2

B. CERVICAL VAGINAL TUMOR

[page 3 of 3]
PATIENT:**PATH #:**

Labeled with the patient's name, labeled "cervical vaginal tumor", and received in formalin is a 110 gram, 13.0 x 10.0 x 2.0 cm aggregate of soft tan-red focally hemorrhagic and focally necrotic tissue fragments. No definite cervical or vaginal tissue is grossly identified. Representative sections.
B1-B3. 2 each

Gross dictated by

OPERATIVE CALL**OPERATIVE CONSULT (GROSS):****PART A. UTERUS, BILATERAL TUBES AND OVARIES:**

- Large necrotic mass filling the endometrial cavity

TISSUE TAKEN FOR

- Tissue given to research

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

Histologic Discrepancy		
Dual/Syncyt. Primary History		
Case is (Check):		

W 2/12/13
1/29/13

Source: NCI Genomic Data Commons file 41829cf8-5bba-4b80-92f7-567ef1d77742 (TCGA-ND-A4WF.6D68C38D-2C12-4C40-ABB1-4E1995BE96C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).